Somatic mutation profile of tumor specimen RC-B6SL-TTP1-A (aliquot RC-B6SL-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SL, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 52.4 years (19,144 days).
Specimen RC-B6SL-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 973f149b-437c-479e-918f-dc1a880aa840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SL-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SL-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b688d8eb-6c23-443f-893c-f750a04c3d5c

The open-access MAF lists 312 somatic variants for this specimen: 222 protein-altering or splice-affecting, 70 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 70, Nonsense Mutation 12, Intron 10, RNA 4, Splice Region 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 2, 5'Flank 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.20T>G p.L7* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | hotspot (GDC flag); catalogued as COSV100837677, COSV62564278, COSV62565442; called by muse, mutect2, varscan2
- AATK | c.653G>A p.R218Q (on ENST00000326724 / NM_001080395.3; = p.R115Q on NM_004920.2) | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as rs866975547, COSV104399821; called by muse, mutect2, varscan2
- ADGRG4 | c.6740A>G p.N2247S | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs755535605, COSV99796355; called by muse, mutect2, varscan2
- ARHGAP19 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100363166; called by muse, mutect2, varscan2
- ARHGAP28 | c.536A>T p.E179V (on ENST00000383472 / NM_001366230.1; = p.E20V on NM_001010000.3) | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs201543358; called by muse, mutect2, varscan2
- ARHGAP31 | c.3777G>T p.K1259N | Missense Mutation (SNP) | VAF 144/387 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99956888; called by muse, mutect2, varscan2
- ARHGEF15 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777832647; called by muse, mutect2, varscan2
- ARHGEF33 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 124/359 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1364601906, COSV67258608; called by muse, mutect2, varscan2
- ARMC4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs181484327, COSV100536459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSD | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 112/159 reads (70%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV99472327; called by muse, mutect2, varscan2
- ASTL | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60904374; called by muse, mutect2, varscan2
- BMP2K | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as rs752677759; called by muse, mutect2, varscan2
- BMPR1B | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs780280883; called by muse, mutect2, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 46/146 reads (32%) | catalogued as rs777474487; called by mutect2, varscan2
- C17orf64 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs769510201, COSV99293430; called by muse, mutect2
- CACNA1S | c.4787G>C p.G1596A | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV62935856; called by muse, mutect2, varscan2
- CCER1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 131/377 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100726980; called by muse, mutect2, varscan2
- CCIN | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs547325705, COSV100631658, COSV58724218; called by muse, mutect2, varscan2
- CD58 | c.84T>G p.C28W | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65664713; called by muse, mutect2, varscan2
- CFAP221 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs771543800, COSV99732217; called by muse, mutect2, varscan2
- CFAP57 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs549675222; called by muse, mutect2, varscan2
- CFTR | c.100T>A p.L34M | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.86); catalogued as CD962505; called by muse, mutect2, varscan2
- CHRNA3 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58775073; called by muse, mutect2, varscan2
- CHST15 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748902428, COSV60564798; called by muse, mutect2, varscan2
- CLN6 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99992617; called by muse, mutect2, varscan2
- COL11A2 | c.1234C>A p.P412T (on ENST00000341947 / NM_080680.3; = p.P305T on NM_080679.2) | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1422068921; called by muse, mutect2, varscan2
- CXADR | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs760582039, COSV53031716; called by muse, mutect2, varscan2
- CYP4F12 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.258); catalogued as rs1398322477; called by muse, mutect2, varscan2
- DEFB114 | c.195A>C p.E65D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs371645852; called by muse, mutect2, varscan2
- DNAH11 | c.2833C>T p.Q945* | Nonsense Mutation (SNP) | VAF 106/293 reads (36%) | catalogued as COSV60982581; called by muse, mutect2, varscan2
- DNAH5 | c.13840C>A p.L4614I | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54234659; called by muse, mutect2, varscan2
- DSCAM | c.4039C>T p.R1347C | Missense Mutation (SNP) | VAF 137/276 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs765825981, COSV68026060; called by muse, mutect2, varscan2
- EDNRB | c.536C>T p.P179L (on ENST00000377211 / NM_001201397.1; = p.P89L on NM_000115.5) | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57524395; called by muse, mutect2, varscan2
- EFCAB3 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1056642; called by muse, mutect2, varscan2
- EFEMP1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs999879979, COSV62616270, COSV62616839; called by muse, mutect2, varscan2
- EHBP1L1 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1321476230; called by muse, mutect2, varscan2
- ELAPOR1 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771601560, COSV100884500; called by muse, mutect2, varscan2
- EML4 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1467753952; called by muse, mutect2, varscan2
- EMP1 | c.427T>G p.F143V | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1307636767; called by muse, mutect2, varscan2
- EPB41L3 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1009731371, COSV59456726; called by muse, mutect2, varscan2
- FASTK | c.1411C>G p.R471G | Missense Mutation (SNP) | VAF 112/320 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99879799; called by muse, mutect2, varscan2
- FGF6 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 140/383 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57404384, COSV57405588; called by muse, mutect2, varscan2
- FLNC | c.6773C>T p.S2258L | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs762051422, COSV57956300; called by muse, mutect2, varscan2
- FOXB2 | c.132G>C p.M44I | Missense Mutation (SNP) | VAF 146/278 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65022923; called by muse, mutect2, varscan2
- GCC2 | c.3317A>G p.E1106G | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs771506645; called by muse, mutect2, varscan2
- GDF3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766154682; called by muse, mutect2, varscan2
- GRIN2A | c.3052G>A p.V1018M | Missense Mutation (SNP) | VAF 99/328 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775756583, COSV58020685; called by muse, mutect2, varscan2
- GRIN3A | c.3302C>T p.T1101M | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as rs762678837, COSV62454480; called by muse, mutect2, varscan2
- HCN4 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 131/373 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs777209839; called by muse, mutect2, varscan2
- HPSE2 | c.13T>G p.C5G | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65187019; called by muse, mutect2, varscan2
- IDO1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs372512518, COSV53713468; called by muse, mutect2, varscan2
- IGF2BP2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs908449835, COSV60487187; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.764G>A p.R255H (on ENST00000485419 / NM_001197113.1; = p.R179H on NM_014575.3) | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs771771676; called by muse, mutect2, varscan2
- KCNB2 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 139/377 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs563196308, COSV73049377; called by muse, mutect2, varscan2
- KRT75 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 148/405 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52871807; called by muse, mutect2, varscan2
- LZTS3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs751829850, COSV61276898; called by muse, mutect2, varscan2
- MEFV | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs563470459, COSV54818563; called by muse, mutect2, varscan2
- MLH3 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs765313787, COSV53155991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP11 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 145/389 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1569157278, COSV53157396; called by muse, mutect2, varscan2
- MYBPC2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63095892; called by muse, mutect2, varscan2
- NOTUM | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101293815; called by muse, mutect2, varscan2
- OBSCN | c.13132G>A p.E4378K | Missense Mutation (SNP) | VAF 284/535 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs773247093, COSV52785007; called by muse, mutect2, varscan2
- PARD3B | c.3542G>A p.R1181H (on ENST00000406610 / NM_001302769.2; = p.R1112H on NM_057177.7) | Missense Mutation (SNP) | VAF 127/357 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs374968951, COSV100592411; called by muse, mutect2, varscan2
- PCDHB7 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1554280024, COSV50770160; called by muse, mutect2, varscan2
- PCDHGC4 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 139/394 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.541); catalogued as rs747722740, COSV99338413; called by muse, mutect2, varscan2
- PIGR | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs201367607, COSV62904384; called by muse, mutect2, varscan2
- PLCH2 | c.3572G>A p.R1191H | Missense Mutation (SNP) | VAF 210/506 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs772440884; called by muse, mutect2, varscan2
- PRDM1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs1367869245, COSV100958936; called by muse, mutect2, varscan2
- PRKD1 | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 131/496 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV59563847; called by muse, mutect2, varscan2
- PTPRU | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs769159207, COSV60533610; called by muse, mutect2, varscan2
- RALYL | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV72823456; called by muse, mutect2, varscan2
- RCC1L | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs1554446585; called by muse, mutect2, varscan2
- RFPL4A | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 73/1050 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV70455802; called by muse, mutect2
- RFPL4AL1 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 58/998 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1366494442; called by muse, mutect2
- RNF213 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1348905002, COSV100173440; called by muse, mutect2, varscan2
- RPS6KL1 | c.264C>T p.H88= | Splice Region (SNP) | VAF 57/182 reads (31%) | catalogued as rs565747542; called by muse, mutect2, varscan2
- SCN4A | c.4674G>T p.E1558D | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV71128252; called by muse, mutect2, varscan2
- SH3BP4 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs758813200; called by muse, varscan2
- SH3BP4 | c.2255C>T p.T752M | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746964092, COSV60642228; called by muse, varscan2
- SH3KBP1 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 61/85 reads (72%) | catalogued as COSV65643939, COSV65644186; called by muse, mutect2, varscan2
- SLC23A1 | c.1618A>G p.S540G | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99497187; called by muse, mutect2, varscan2
- SOCS3 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs966458254; called by muse, mutect2, varscan2
- SOX1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 135/340 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1423308332; called by muse, mutect2, varscan2
- SP140 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs757998046, COSV100613340; called by muse, mutect2, varscan2
- SPTBN5 | c.9149C>T p.A3050V | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs376374505; called by muse, mutect2, varscan2
- SSX2IP | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV99046145; called by muse, mutect2, varscan2
- SYNGAP1 | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1233028040; called by muse, mutect2, varscan2
- TET2 | c.4478A>C p.K1493T | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV54408621; called by muse, mutect2, varscan2
- THSD7A | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.091); catalogued as COSV70267345; called by muse, mutect2, varscan2
- TMCC2 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 191/366 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs143084368; called by muse, mutect2, varscan2
- TRAF3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.087); catalogued as rs145947234; called by muse, mutect2, varscan2
- TRDN | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.956); catalogued as COSV100521810; called by muse, mutect2, varscan2
- USF2 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 126/205 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55885166; called by muse, mutect2, varscan2
- VGLL3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 144/372 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs1032057055, COSV101051878, COSV67352465; called by muse, mutect2, varscan2
- ZFP36L2 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 158/389 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as rs767461690; called by muse, mutect2, varscan2
- ZNF135 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 191/374 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57885576; called by muse, mutect2, varscan2
- ZNF614 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV54544851; called by muse, mutect2, varscan2
- ZNF649 | c.70T>G p.F24V | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1289503831; called by muse, mutect2, varscan2
- ZNF804B | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs758841751, COSV60822447; called by muse, mutect2, varscan2
- ABCA1 | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- AC006538.2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAP2 | c.1465A>C p.K489Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ADGRB3 | c.4032A>C p.K1344N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRG6 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.07); called by muse, mutect2
- AGBL1 | c.2375_2401del p.X792_splice | Splice Site (DEL) | VAF 49/153 reads (32%) | called by mutect2, pindel, varscan2
- AKT2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG13 | c.1975A>C p.R659= | Splice Region (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- ANAPC16 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANK3 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANO8 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ARHGAP19 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP6 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 190/260 reads (73%) | called by muse, mutect2, varscan2
- ASXL3 | c.5317C>A p.L1773I | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATAD2B | c.458A>T p.D153V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AVPR2 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 132/181 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- BEND3 | c.995T>G p.L332R | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- BOD1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- BRWD1 | c.788T>G p.V263G | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CAGE1 | c.2096A>G p.E699G (on ENST00000512086; = p.E563G on NM_205864.3) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CASKIN1 | c.2080T>C p.S694P | Missense Mutation (SNP) | VAF 152/442 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D2A | c.3673G>T p.G1225C | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCDC136 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.11816A>T p.E3939V | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CDH20 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDYL | c.1604T>C p.V535A (on ENST00000328908 / NM_001368125.1; = p.V481A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CEP295 | c.4511A>G p.D1504G | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CES5A | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPB1 | c.1379G>A p.W460* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 129/192 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DLL4 | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH9 | c.6115C>T p.H2039Y | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1A1 | c.210_211insTA p.I71* | Frame Shift Ins (INS) | VAF 94/278 reads (34%) | called by mutect2, pindel, varscan2
- EFHC1 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC3 | c.809T>A p.F270Y | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- FAM43B | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXA1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.12986T>A p.I4329N | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- FUT4 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GARRE1 | c.1318A>C p.S440R | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GJD3 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 94/254 reads (37%) | called by muse, mutect2, varscan2
- GLB1L3 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GRM7 | c.1761C>G p.H587Q | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GSR | c.1029T>G p.S343R | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- H3C13 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HCN1 | c.1810A>T p.K604* | Nonsense Mutation (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- HECTD3 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- HMCN2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- HOXD12 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 167/414 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- HRNR | c.6775C>T p.Q2259* | Nonsense Mutation (SNP) | VAF 80/800 reads (10%) | called by muse, mutect2, varscan2
- HSF2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2
- INPP5J | c.2117C>A p.T706K (on ENST00000331075 / NM_001284285.2; = p.T338K on NM_001002837.2) | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IRAK1 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 104/142 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRF2BP2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IRF2BP2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNK12 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIAA0586 | c.4078C>A p.Q1360K (on ENST00000619416 / NM_001244190.2; = p.Q1299K on NM_014749.5) | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1755 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KLC2 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP2 | c.7442A>G p.Y2481C | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4B | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 142/520 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LRRC55 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MAP2 | c.4607A>G p.E1536G | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP4K2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MDGA2 | c.2295G>T p.K765N (on ENST00000399232 / NM_001113498.2; = p.K467N on NM_182830.4) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- MEGF8 | c.6868G>C p.V2290L (on ENST00000251268 / NM_001271938.2; = p.V2223L on NM_001410.3) | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MTBP | c.2540T>G p.I847S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MTTP | c.-8_17del | Translation Start Site (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- NANOGNB | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEK10 | c.2791A>C p.S931R | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NHSL1 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHP3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR13C2 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, varscan2
- OR4A15 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- OSTC | c.393T>G p.S131R | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PARP16 | c.247T>C p.W83R | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHGB5 | c.1274A>G p.K425R | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PDIA5 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PLAA | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- PNPLA3 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF19 | c.1347G>C p.R449S | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PRPF39 | c.1362G>T p.L454F | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRR14L | c.4482A>C p.K1494N | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PRSS41 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- RAG1 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 187/376 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RD3L | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RIOX2 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- RNF168 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF180 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SDR42E1 | c.1072A>G p.S358G | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5A | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERHL2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC12A2 | c.2149C>A p.L717I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC24A3 | c.1608G>A p.G536= | Splice Region (SNP) | VAF 66/198 reads (33%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLITRK1 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- SMARCA4 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SOGA3 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA5L1 | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SSX2IP | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- STON2 | c.209A>T p.D70V | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STOX2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYCP2L | c.1398A>C p.Q466H | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TBC1D19 | c.1547T>G p.L516R | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TBC1D21 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEDC1 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TMTC1 | c.2135T>G p.L712R (on ENST00000539277 / NM_001193451.2; = p.L604R on NM_175861.3) | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNKS | c.2192A>G p.E731G | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TNRC6B | c.3155G>A p.G1052E (on ENST00000454349 / NM_001162501.2; = p.G999E on NM_015088.3) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.466_477del p.R156_A159del | In Frame Del (DEL) | VAF 107/193 reads (55%) | called by mutect2, pindel, varscan2
- TRAJ52 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TRBC1 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 131/257 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TRIM9 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 141/440 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.229); called by mutect2, varscan2
- TXNL4A | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- USH2A | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- WDFY3 | c.1600A>T p.R534* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- ZBTB22 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 226/577 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX3 | c.2366C>A p.S789Y | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZFP36L2 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 92/247 reads (37%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- ZNF180 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 82/240 reads (34%) | called by muse, mutect2, varscan2
- ZNF415 | c.1363T>G p.L455V | Missense Mutation (SNP) | VAF 102/387 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ZNF765 | c.518T>A p.L173* | Nonsense Mutation (SNP) | VAF 92/404 reads (23%) | called by muse, mutect2, varscan2
- ACTL7B | c.492G>A p.A164= | Silent (SNP) | VAF 156/445 reads (35%) | catalogued as rs114146670, COSV65928128; called by muse, mutect2, varscan2
- ANO5 | c.786A>G p.E262= | Silent (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- APOBR | c.2118G>A p.P706= (on ENST00000431282; = p.P715= on NM_018690.4) | Silent (SNP) | VAF 162/430 reads (38%) | catalogued as rs371541028; called by muse, mutect2, varscan2
- ATP5IF1 | c.75C>T p.F25= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV55282877; called by muse, mutect2
- BMP4 | c.336C>T p.S112= | Silent (SNP) | VAF 67/288 reads (23%) | called by muse, mutect2, varscan2
- BNC2 | c.1110A>G p.E370= | Silent (SNP) | VAF 135/359 reads (38%) | called by muse, mutect2, varscan2
- C2CD2 | c.1101G>A p.G367= | Silent (SNP) | VAF 81/307 reads (26%) | called by muse, mutect2, varscan2
- CACNG7 | c.786C>T p.I262= | Silent (SNP) | VAF 268/537 reads (50%) | called by muse, mutect2, varscan2
- CAPN9 | c.1041C>T p.H347= | Silent (SNP) | VAF 106/407 reads (26%) | called by muse, mutect2, varscan2
- CCDC54 | c.507G>A p.L169= | Silent (SNP) | VAF 96/282 reads (34%) | called by muse, mutect2, varscan2
- CITED2 | c.477G>A p.K159= | Silent (SNP) | VAF 119/319 reads (37%) | catalogued as rs1232686892; called by muse, mutect2, varscan2
- CPLX2 | c.270C>T p.C90= | Silent (SNP) | VAF 117/340 reads (34%) | catalogued as rs544929121; called by muse, mutect2, varscan2
- CRABP1 | c.291G>A p.T97= | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as rs747438217, COSV55115753, COSV55115769; called by muse, varscan2
- DCBLD1 | c.426T>G p.G142= | Silent (SNP) | VAF 81/234 reads (35%) | called by muse, mutect2, varscan2
- DEFB121 | c.144T>C p.A48= | Silent (SNP) | VAF 141/320 reads (44%) | catalogued as rs768516110; called by muse, mutect2, varscan2
- DMRT3 | c.750G>A p.P250= | Silent (SNP) | VAF 110/231 reads (48%) | catalogued as rs199530929; called by muse, mutect2, varscan2
- DNM1 | c.2154G>A p.S718= | Silent (SNP) | VAF 126/345 reads (37%) | catalogued as rs751222927; called by muse, mutect2, varscan2
- DTHD1 | c.2211C>T p.F737= (on ENST00000456874; = p.F572= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/285 reads (39%) | called by muse, mutect2, varscan2
- EN1 | c.732G>A p.E244= | Silent (SNP) | VAF 119/332 reads (36%) | called by muse, mutect2, varscan2
- ERLEC1 | c.987G>A p.L329= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs890792177, COSV51751132; called by muse, mutect2, varscan2
- EXOC6B | c.441G>A p.L147= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs767505304; called by muse, mutect2, varscan2
- FLRT2 | c.1188G>A p.T396= | Silent (SNP) | VAF 140/519 reads (27%) | catalogued as rs200412416, COSV58143947; called by muse, mutect2, varscan2
- FLRT3 | c.1815G>A p.S605= | Silent (SNP) | VAF 86/239 reads (36%) | catalogued as rs766612204, COSV54011774; called by muse, mutect2, varscan2
- FOXA2 | c.81C>T p.S27= (on ENST00000377115 / NM_153675.3; = p.S33= on NM_021784.5) | Silent (SNP) | VAF 81/240 reads (34%) | called by muse, mutect2, varscan2
- GADL1 | c.840T>A p.A280= | Silent (SNP) | VAF 45/167 reads (27%) | called by muse, mutect2, varscan2
- GRAMD2A | c.783G>A p.G261= | Silent (SNP) | VAF 119/274 reads (43%) | catalogued as rs762792158, COSV59034472, COSV59034720; called by muse, mutect2, varscan2
- HEXA | c.735C>T p.Y245= | Silent (SNP) | VAF 76/216 reads (35%) | catalogued as rs777460475, COSV51509610; called by muse, mutect2, varscan2
- HOXA3 | c.849G>A p.L283= | Silent (SNP) | VAF 107/308 reads (35%) | called by muse, mutect2, varscan2
- HOXC13 | c.96C>A p.G32= | Silent (SNP) | VAF 146/382 reads (38%) | catalogued as rs772231269; called by muse, varscan2
- IGFALS | c.573C>T p.R191= | Silent (SNP) | VAF 137/359 reads (38%) | catalogued as rs778091834; called by muse, mutect2, varscan2
- IGFBP1 | c.213C>T p.C71= | Silent (SNP) | VAF 123/339 reads (36%) | catalogued as rs1162202771; called by muse, mutect2, varscan2
- IGHV3-48 | c.111G>C p.L37= | Silent (SNP) | VAF 77/293 reads (26%) | called by muse, mutect2, varscan2
- KCNK2 | c.192G>A p.T64= (on ENST00000444842 / NM_001017425.3; = p.T49= on NM_014217.4) | Silent (SNP) | VAF 92/363 reads (25%) | catalogued as COSV67207587; called by muse, mutect2, varscan2
- KIF15 | c.699G>A p.S233= | Silent (SNP) | VAF 74/195 reads (38%) | catalogued as rs200877926; called by muse, mutect2, varscan2
- LMOD2 | c.756C>T p.A252= | Silent (SNP) | VAF 110/318 reads (35%) | catalogued as rs573835086, COSV101505398; called by muse, mutect2, varscan2
- MAPKBP1 | c.3930G>A p.L1310= (on ENST00000456763 / NM_001128608.2; = p.L1304= on NM_014994.3) | Silent (SNP) | VAF 116/358 reads (32%) | called by muse, mutect2, varscan2
- MOS | c.141G>A p.P47= | Silent (SNP) | VAF 134/366 reads (37%) | called by muse, mutect2, varscan2
- NINL | c.2106C>T p.R702= | Silent (SNP) | VAF 84/231 reads (36%) | catalogued as rs200042827; called by muse, mutect2, varscan2
- NT5DC3 | c.6C>T p.T2= | Silent (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- NWD2 | c.4893C>T p.I1631= | Silent (SNP) | VAF 103/300 reads (34%) | called by muse, mutect2, varscan2
- PABPC4 | c.111G>A p.V37= | Silent (SNP) | VAF 154/383 reads (40%) | called by muse, mutect2, varscan2
- PCDHA2 | c.147G>T p.A49= | Silent (SNP) | VAF 216/612 reads (35%) | catalogued as rs144324178, COSV65370513; called by muse, mutect2, varscan2
- PCDHGA12 | c.2019G>A p.A673= | Silent (SNP) | VAF 222/682 reads (33%) | catalogued as rs776657082; called by muse, mutect2, varscan2
- PCNX1 | c.6543C>T p.S2181= | Silent (SNP) | VAF 128/450 reads (28%) | catalogued as rs369821499; called by muse, mutect2, varscan2
- PLEKHG4B | c.2808C>T p.P936= (on ENST00000283426; = p.P1292= on NM_052909.5) | Silent (SNP) | VAF 85/250 reads (34%) | catalogued as rs146763332; called by muse, mutect2, varscan2
- POTEA | c.1411T>C p.L471= (on ENST00000519951 / NM_001005365.2; = p.L425= on NM_001002920.1) | Silent (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- PPARD | c.822C>T p.F274= | Silent (SNP) | VAF 113/309 reads (37%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.477C>T p.F159= | Silent (SNP) | VAF 171/826 reads (21%) | called by muse, mutect2
- PRDM1 | c.1062C>T p.S354= | Silent (SNP) | VAF 114/243 reads (47%) | called by muse, mutect2, varscan2
- PTBP1 | c.774C>T p.S258= | Silent (SNP) | VAF 131/217 reads (60%) | catalogued as rs200335883; called by muse, mutect2, varscan2
- PTPRQ | c.4977G>C p.G1659= (on ENST00000616559; = p.G1617= on NM_001145026.2) | Silent (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- PXDNL | c.3297G>A p.P1099= | Silent (SNP) | VAF 142/371 reads (38%) | catalogued as rs1429276841; called by muse, mutect2, varscan2
- RASA2 | c.39C>T p.S13= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2, varscan2
- RCC1 | c.423C>T p.F141= | Silent (SNP) | VAF 98/263 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.1320G>A p.A440= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as rs887478410, COSV63712174; called by muse, mutect2, varscan2
- SETSIP | c.132G>A p.P44= | Silent (SNP) | VAF 128/327 reads (39%) | catalogued as rs892865314; called by muse, mutect2, varscan2
- SLC12A5 | c.2910C>G p.A970= (on ENST00000454036 / NM_001134771.2; = p.A947= on NM_020708.5) | Silent (SNP) | VAF 134/300 reads (45%) | called by muse, mutect2, varscan2
- SLC28A2 | c.60G>A p.V20= | Silent (SNP) | VAF 87/236 reads (37%) | called by muse, mutect2, varscan2
- SORBS1 | c.2844C>A p.R948= (on ENST00000361941 / NM_001034954.2; = p.R598= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/232 reads (35%) | called by muse, mutect2, varscan2
- SPATA18 | c.951G>A p.A317= | Silent (SNP) | VAF 95/312 reads (30%) | catalogued as COSV54642522; called by muse, mutect2, varscan2
- SPZ1 | c.894G>A p.S298= | Silent (SNP) | VAF 80/256 reads (31%) | catalogued as rs369209245; called by muse, mutect2
- STK32B | c.114C>T p.C38= | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as rs576529233; called by muse, mutect2, varscan2
- TAGLN2 | c.219G>A p.G73= | Silent (SNP) | VAF 140/281 reads (50%) | called by muse, mutect2, varscan2
- TMEM167A | c.66T>C p.A22= | Silent (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.699C>T p.I233= | Silent (SNP) | VAF 106/308 reads (34%) | called by muse, mutect2, varscan2
- TPCN1 | c.2325G>A p.E775= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- USP25 | c.1542G>A p.S514= | Silent (SNP) | VAF 78/290 reads (27%) | catalogued as rs749546781, COSV53489014; called by muse, mutect2, varscan2
- ZNF180 | c.480C>T p.D160= | Silent (SNP) | VAF 81/238 reads (34%) | called by muse, mutect2, varscan2
- ZNF383 | c.1176A>G p.K392= | Silent (SNP) | VAF 73/271 reads (27%) | called by muse, mutect2, varscan2
- ZNF479 | c.732G>A p.E244= | Silent (SNP) | VAF 96/295 reads (33%) | catalogued as rs1554400273, COSV58637499; called by muse, mutect2, varscan2
- CA6 | c.845-215C>T | Intron (SNP) | VAF 101/306 reads (33%) | catalogued as rs1181210482; called by muse, mutect2, varscan2
- CHD3 | chr17:7885010 C>T | 5'Flank (SNP) | VAF 10/110 reads (9%) | catalogued as COSV57881166; called by muse, mutect2
- DMBT1L1 | n.4816C>T | RNA (SNP) | VAF 119/290 reads (41%) | called by muse, mutect2, varscan2
- DST | c.4296+4308del | Intron (DEL) | VAF 94/320 reads (29%) | called by mutect2, pindel, varscan2
- FADS2 | chr11:61826337 C>T | 5'Flank (SNP) | VAF 60/175 reads (34%) | catalogued as rs766559026; called by muse, mutect2, varscan2
- FMN1 | c.2044-2207T>C | Intron (SNP) | VAF 114/314 reads (36%) | called by muse, mutect2, varscan2
- FOLH1B | n.731T>C | RNA (SNP) | VAF 52/150 reads (35%) | called by muse, mutect2, varscan2
- HMCN2 | c.14266+110A>C | Intron (SNP) | VAF 99/242 reads (41%) | called by muse, mutect2, varscan2
- HTR3B | c.53-17G>T | Intron (SNP) | VAF 100/270 reads (37%) | catalogued as COSV99491715; called by muse, mutect2, varscan2
- KASH5 | c.*34C>T | 3'UTR (SNP) | VAF 95/262 reads (36%) | called by muse, mutect2, varscan2
- LINC02873 | n.52G>A | RNA (SNP) | VAF 71/159 reads (45%) | catalogued as rs373033298; called by muse, mutect2, varscan2
- MUC19 | n.16168T>A | RNA (SNP) | VAF 233/627 reads (37%) | called by muse, mutect2, varscan2
- NFIB | c.1245+4124G>A | Intron (SNP) | VAF 96/259 reads (37%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-38605G>A | Intron (SNP) | VAF 83/223 reads (37%) | catalogued as rs1318459860, COSV58143723; called by muse, mutect2, varscan2
- PRDM11 | chr11:45226988 T>G | 3'Flank (SNP) | VAF 115/343 reads (34%) | called by muse, mutect2, varscan2
- RNA5SP308 | chr10:28873259 A>C | 3'Flank (SNP) | VAF 38/109 reads (35%) | called by muse, mutect2, varscan2
- SCN5A | c.612-767C>A | Intron (SNP) | VAF 64/140 reads (46%) | called by muse, mutect2, varscan2
- SLC13A2 | c.232-28G>A | Intron (SNP) | VAF 151/400 reads (38%) | catalogued as rs184808575, COSV100120508; called by muse, mutect2, varscan2
- SOHLH1 | c.*376G>A | 3'UTR (SNP) | VAF 66/181 reads (36%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3198G>A | Intron (SNP) | VAF 125/356 reads (35%) | called by muse, mutect2, varscan2
